Somatic mutation profile of tumor specimen TCGA-CN-A6V7-01A (aliquot TCGA-CN-A6V7-01A-12D-A34J-08) from TCGA case TCGA-CN-A6V7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 40.8 years (14,895 days).
Specimen TCGA-CN-A6V7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d5ab9f5-744b-470c-9fc5-a9533c95eb3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A6V7-10A (Blood Derived Normal), aliquot TCGA-CN-A6V7-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d607caa-be91-42f3-ab0a-b9774de70cc2

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 30, Silent 15, Nonsense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 62/70 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB2 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs760929579, COSV57080674; called by muse, mutect2, varscan2
- ANKS1B | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100243789; called by muse, mutect2, varscan2
- AP002748.5 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100567775; called by muse, mutect2, varscan2
- APP | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755703063; called by muse, mutect2, varscan2
- C2orf16 | c.3886C>T p.R1296* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as rs530926787, COSV62676678; called by muse, mutect2, varscan2
- CIR1 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100564910; called by muse, mutect2, varscan2
- CLDN17 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs563734261, COSV54524876; called by muse, mutect2, varscan2
- ECEL1 | c.1945T>C p.C649R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100458543; called by muse, mutect2, varscan2
- FAM71B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs745867472, COSV57227431; called by muse, mutect2, varscan2
- FCRL5 | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV100708671; called by muse, mutect2, varscan2
- GALR2 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.336); catalogued as COSV100135009; called by muse, mutect2, varscan2
- HECA | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100866146, COSV100866167; called by muse, varscan2
- MAFB | c.806A>G p.E269G | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965025; called by muse, mutect2, varscan2
- NLRP9 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV100242767, COSV60460143; called by muse, mutect2, varscan2
- NOL10 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs868041961, COSV62038190; called by muse, mutect2, varscan2
- OPN3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1213209489, COSV59363910; called by muse, mutect2, varscan2
- OR10AG1 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100400000; called by muse, mutect2, varscan2
- OR11H1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99421677; called by mutect2, varscan2
- ORC6 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV99530820; called by muse, mutect2, varscan2
- PCLO | c.13982C>T p.S4661F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100429088; called by muse, mutect2, varscan2
- PKHD1 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100581888, COSV61893434; called by muse, mutect2, varscan2
- PRICKLE2 | c.2617G>A p.G873S (on ENST00000295902; = p.G817S on NM_198859.4) | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1018298909, COSV55766053, COSV99896819; called by muse, mutect2, varscan2
- RGS17 | c.77_79del p.N26del | In Frame Del (DEL) | VAF 32/143 reads (22%) | catalogued as rs753375713; called by pindel, varscan2
- RNF213 | c.13851G>C p.Q4617H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV100300009, COSV60405874; called by muse, mutect2, varscan2
- SCAF8 | c.1985C>A p.S662* | Nonsense Mutation (SNP) | VAF 75/135 reads (56%) | catalogued as COSV100781296; called by muse, mutect2, varscan2
- TEX47 | c.570A>C p.K190N | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99787207; called by muse, mutect2, varscan2
- THAP10 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV99997726; called by muse, mutect2, varscan2
- WAC | c.1613C>G p.S538* | Nonsense Mutation (SNP) | VAF 50/127 reads (39%) | catalogued as COSV100610933; called by muse, mutect2, varscan2
- YTHDC2 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV99362977, COSV99363041; called by muse, mutect2, varscan2
- ZC3H12C | c.1333G>C p.D445H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99584723; called by muse, mutect2, varscan2
- ZFP2 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100797019; called by muse, mutect2, varscan2
- ZNF143 | c.1864A>G p.I622V | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV100217753; called by muse, mutect2, varscan2
- ZNF627 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780005956, COSV100741447; called by muse, mutect2, varscan2
- ANK1 | c.2628G>A p.E876= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99224481; called by muse, mutect2, varscan2
- ANKRD26 | c.2733G>A p.S911= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs996859183, COSV101063018; called by muse, mutect2, varscan2
- CDNF | c.153G>A p.L51= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as COSV101012363; called by muse, mutect2, varscan2
- HAPLN3 | c.522C>T p.N174= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs781710759, COSV61362540; called by muse, mutect2, varscan2
- HLCS | c.786A>G p.A262= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100357988; called by muse, mutect2, varscan2
- IRGQ | c.1695C>T p.G565= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1020689328, COSV100338080; called by muse, mutect2
- NEO1 | c.3339C>T p.G1113= | Silent (SNP) | VAF 119/323 reads (37%) | catalogued as rs754629914, COSV56068364; called by muse, mutect2, varscan2
- PAOX | c.1293G>A p.P431= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as rs1009117891, COSV53373773, COSV53375068; called by muse, mutect2, varscan2
- PKD1 | c.9405G>A p.T3135= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs144910188; called by muse, mutect2, varscan2
- POMGNT1 | c.1572G>A p.T524= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs201897676, COSV100915450; called by muse, mutect2, varscan2
- PYCR1 | c.513G>A p.T171= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs375473975; called by muse, mutect2, varscan2
- RAB25 | c.99G>A p.T33= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs373021788; called by muse, mutect2, varscan2
- TFAP2B | c.66C>T p.Y22= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1377078499, COSV99539801; called by muse, mutect2, varscan2
- TMEM130 | c.615C>T p.T205= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs369234660; called by muse, mutect2, varscan2
- ZIC1 | c.462G>A p.A154= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99291675; called by muse, mutect2, varscan2
